Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A8WN, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A8WN-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

ICD-6.3

Adenocarcinoma NOS 8140/3

Site Prostate NOS C61.9

9/23/28/14

FINAL PATHOLOGIC DIAGNOSIS

- A. Soft tissue, peri-prostatic fat, biopsy: Benign fibroadipose tissue, no prostatic epithelium or carcinoma.
- B. Right anterior apex margin, biopsy: Benign prostatic tissue, no carcinoma present.
- C. Right posterior apex margin, biopsy: Fibromuscular tissue, no prostatic epithelium or carcinoma.
- D. Prostate gland, bilateral seminal vesicles, radical prostatectomy:
- Prostate gland: Prostatic adenocarcinoma, Gleason score 3+4=7, confined to prostate, excised; see comment.
- Right and left seminal vesicles: No tumor identified.

COMMENT:

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** Posterior bilateral, apex-base (~ 2 cc; slides D3, D5, D6, D9-D12). Left anterior mid gland, slides D4, D6 (~0.1cc).
- **Estimated volume of tumor:** ~2 cc.
- **Gleason score:** 3+4=7.
- **Estimated volume > Gleason pattern 3:** ~10%.
- **Involvement of capsule:** None.
- **Extraprostatic extension:** None.
- **Margin status for tumor:** Negative.
- **Margin status for benign prostate glands:** Present at inked right base margin (~1 mm).
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** None.
- **Tumor involvement of seminal vesicle:** None.
- **Perineural infiltration:** None.
- **Lymph node status:** None present.
- **AJCC/UICC stage:** pT2cN0.

[page 2 of 3]
Specimen(s) Received

A: Peri-prostatic fat (perm)
B: Right anterior apex margin (perm)
C: Right posterior apex margin (perm)
D: Prostate and seminal vesicles (Perm)

Clinical History

OR Room and Phone # (frozen specimen : interoperative consults only):
Collection Date:
Collection Time:
Relevant History: prostate cancer
Pre-op Diagnosis:

Gross Description

The specimen is received in four parts, each labeled with the patient's name and medical record number. Parts A-C are received in formalin. Part D is received fresh.

Part A, additionally labeled "periprostatic fat," consists of one irregular fragment of rubbery, deep-yellow to red, lobulated soft tissue (3.9 x 1.8 x 0.3 cm). No lymph nodes are identified. The specimen is entirely submitted in cassettes A1 and A2.

Part B, additionally labeled "right anterior apex margin (perm)," consists of one unoriented, irregular fragment of rubbery, deep-brown soft tissue (0.3 x 0.2 x 0.1 cm), entirely submitted in cassette B1.

Part C, additionally labeled "right posterior apex margin (perm)," consists of one unoriented, irregular fragment of rubbery, deep-brown soft tissue (0.4 x 0.2 x 0.1 cm), entirely submitted in cassette C1.

Part D, additionally labeled "prostate and seminal vesicles," consists of a prostate with attached seminal vesicles (37 gm; 3 cm from apex to base x 3.5 cm in width x 3 cm from anterior to posterior). The seminal vesicle/vas deferens bundles (right 4.5 x 2.5 x 1 cm; left 4 x 2 x 0.5 cm) have tan-pink, lobulated cut surfaces.

GROSS ABNORMALITIES: No lesion is identified. The parenchyma is tan-pink and spongy with few rubbery, well-circumscribed, tan periurethral nodules (0.2-0.4 cm in greatest dimension). The anterior fibrous stroma is open. The remaining capsule is ripped and sutured closed.

ORIENTED BY: Anatomic landmarks (seminal vesicles, urethra).

INKING: Anterior right green, anterior left blue, posterior black.

POTENTIAL STUDIES: Snap frozen.

TOTAL NUMBER OF SLICES: (Not including apex and base margin slices): 5.

AVERAGE SLICE THICKNESS: 0.4 cm (for slices 1-4).

CASSETTES: Representative sections are submitted as follows:

Apical margins, entirely submitted in perpendicular sections

D1: Right apex.

D2: Left apex.

Slice 1

D3: Right.

D4: Left.

Slice 2

D5: Right.

D6: Left.

Right anterior quadrant

D7: Slice 3.

D8: Slice 4.

Right posterior quadrant

D9: Slice 3.

[page 3 of 3]
D10: Slice 4.
Left posterior quadrant
D11: Slice 3.
D12: Slice 4.
Left anterior quadrant
D13: Slice 3.
D14: Slice 4.

Bladder margins, entirely submitted in perpendicular sections

D15: Right.
D16: Left.

Prostatic/seminal vesicle junction and cross-section of vas deferens

D17: Right.
D18: Left.

For properly consented patients, sections of the prostate not required by Pathology for diagnosis, and not submitted as described above, have been submitted to the _____ for processing and can also be made available.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations, including prosector work, and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

/Pathology Resident

Electronically signed out on

/Pathologist

Criteria	hw 12/7/13	Yes	No

Source: NCI Genomic Data Commons file 4602c8b5-ff94-415e-b8e4-6a989bea8fa8 (TCGA-V1-A8WN.F25C1C00-CDFE-4ABD-A920-857AFEA691A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).